Somatic mutation profile of tumor specimen TCGA-VD-A8KN-01A (aliquot TCGA-VD-A8KN-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KN, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,935 days).
Specimen TCGA-VD-A8KN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1d65547-2a83-4431-ab38-0e8b5b649c05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KN-10B (Blood Derived Normal), aliquot TCGA-VD-A8KN-10B-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c392db-733f-4216-8808-a7d9cb6eae96

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 31/87 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAM71A | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs528047581, COSV54236822; called by muse, mutect2, varscan2
- IVL | c.1623G>C p.E541D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.963); catalogued as rs1297610112; called by muse, mutect2, varscan2
- MEAK7 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs755637814, COSV100640392; called by muse, mutect2, varscan2
- MINK1 | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs755386461; called by muse, mutect2, varscan2
- MYO15A | c.6058G>T p.A2020S | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1173298214; called by muse, mutect2, varscan2
- OBSL1 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371966827, COSV54722843; called by muse, mutect2, varscan2
- OR2L2 | c.207C>G p.D69E | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV63558123; called by muse, mutect2, varscan2
- OR4E2 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs376029887, COSV57731883; called by muse, mutect2, varscan2
- LRRC42 | c.615G>A p.Q205= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- PPIL2 | c.613C>A p.R205= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV58605579; called by muse, mutect2
